CPTAC case C3L-02708 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5735655b-b57a-4a27-8fbe-4e4a24150b1c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1973; Vital status: Dead; Days to death: 738 days (2.0 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Parietal lobe; Age at diagnosis: 43.8 years (16,016 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 738 days (2.0 years); Progression or recurrence: yes; Days to recurrence: 525 days (1.4 years); Days to last follow up: 738 days (2.0 years).
   Pathology details: Greatest tumor dimension: 4 cm.

Follow-up (2 entries)
- Days to follow up: 360 days; Disease response: With Tumor; Karnofsky performance status: 90.
- Days to follow up: 738 days (2.0 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 525 days (1.4 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 166 kg; Height: 188 cm; BMI: 46.97.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02708-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 120 mg; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02708-21: Section location: Parietal Lobe; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3L-02708-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 75 mg; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02708-22: Section location: Parietal Lobe; Percent tumor nuclei: 85; Percent necrosis: 7.
- Sample C3L-02708-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 2 days; Method of sample procurement: Blood Draw.
